Somatic mutation profile of tumor specimen C3L-06074-54 (aliquot CPT0371170002) from CPTAC case C3L-06074, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 30.9 years (11,274 days).
Specimen C3L-06074-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ac716e7-63b3-4c88-8860-ffe4be2e61cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06074-50 (Buccal Cell Normal), aliquot CPT0371120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cd1f466-3f08-4438-a52e-a3f14cc6bfa5

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT31 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs767887288, COSV52436448; called by muse, mutect2
- MUC16 | c.31729G>A p.A10577T | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.224); catalogued as rs1435695123; called by muse, mutect2
- PAICS | c.496A>C p.S166R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
